Surgical pathology report (de-identified scan), TCGA case TCGA-30-1859, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1859-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED]
Type: Surgical Pathology
Pathology Report: [REDACTED]

Report Status: Final

OPERATION DATE: [REDACTED]
CLINICAL DATA: [REDACTED]

ACCESSIONED ON: [REDACTED]

[REDACTED] with ovarian cancer.

TCGA-30-1859

*** FINAL DIAGNOSIS ***

OVARY/TUBE (LEFT):

INVASIVE SEROUS PAPILLARY CARCINOMA, EXTENDING INTO FALLOPIAN TUBE.

ADNEXA (RIGHT), EXCISION:

INVASIVE SEROUS PAPILLARY CARCINOMA, INVOLVING FALLOPIAN TUBE.

UTERUS AND CERVIX, EXCISION:

CERVIX:

SQUAMOUS MUCOSA WITH PARAKERATOSIS.

ENDOMETRIUM:

PROLIFERATIVE PATTERN ENDOMETRIUM. LEIOMYOMA.

MYOMETRIUM:

SEROSA WITH PARAKERATOSIS; METASTATIC SEROUS PAPILLARY CARCINOMA.

OMENTUM, EXCISION:

METASTATIC SEROUS CARCINOMA WITH PSAMMOMA BODIES.

APPENDIX, APPENDECTOMY:

METASTATIC SEROUS CARCINOMA.

SOFT TISSUE (UMBILICAL NODULE), EXCISION:

METASTATIC SEROUS CARCINOMA.

THE FROZEN SECTION DIAGNOSIS IS CONFIRMED.

*** IMMUNOHISTOCHEMISTRY Addendum ***

RESULTS OF IMMUNOHISTOCHEMICAL STAINING FOR RECEPTOR PROTEINS

Ovary and Tube (Left, block C):

The tumor cells do not stain for estrogen receptor protein.

The tumor cells do not stain for progesterone receptor protein.

The tumor cells do not show overexpression of HER-2/c-erbB-2.

The tumor cells do not stain with c-kit.

See note.

GROSS DESCRIPTION:

Received fresh in the Frozen Section Lab, labeled with the patient's name, unit number, and "left ovary and tube" is a 12.0 x 11.0 x 10.0 cm multilocular ovary, with attached fallopian tube measuring 5.8 cm. The surface of the ovary is smooth and glistening in some areas with polypoid papillary projections in

[page 2 of 3]
others. One of the polypoid projections is adherent to the fimbriae of the fallopian tube. These projections range in size from 0.5 cm to 3.0 cm. The specimen is opened to reveal multilocular cysts containing tan-brown serous fluid. Some cyst linings are smooth and glistening and others have polypoid or nodular excrescences. Representative sections of the nodule and excrescences are frozen as FX #1 and 2 and now in cassette A and B. Further representative sections are submitted in cassettes C-E, with outer inked surface in cassette E. Representative sections of the fallopian tube and fimbriae with nodule are submitted in cassettes F and G. A photograph of the specimen has been taken.

TCGA-30-1859

Received fresh, labeled with the patient's name, unit number, and "right adnexa" is a multi-cystic ovary, which is partially cystic and partially solid measures 9.0 x 8.0 x 4.0 cm. The fallopian tube measuring 5.0 cm in length and 0.5 cm in diameter. The surface of the ovary is mostly covered in polypoid, papillary brown and beefy pink excrescences, with some areas having a smooth glistening surface. The specimen is opened to reveal multiple excrescences, some papillary and polypoid and other nodular ranging in size from 2.5 cm to 4.0 cm. Some of the cyst lining is smooth. The fallopian tube is serially sectioned and grossly unremarkable. There are prominent vessels in the soft tissue between the fallopian tube and the ovary. Representative sections of the ovary are submitted in cassettes H-J with black ink on the outer surface in cassette H and representative sections of the fallopian tube are submitted in cassette K.

Received fresh, labeled with the patient's name, unit number, and "uterus and cervix" is a 150 gm uterus measuring 9.0 x 5.5 x 4.0 cm. The serosal surface is smooth and glistening with a small white plaque measuring 0.5 cm in greatest dimension adherent to the posterior wall. The rest of the serosal surface is grossly unremarkable. The cervix is slit-shaped and measures 0.7 cm. The specimen is bivalved to reveal a grossly unremarkable endocervical canal measuring 3.0 cm. The endometrial cavity is triangular and measures 4.5 x 2.5 x 0.1 cm. The specimen is serially sectioned to reveal a myometrial nodule in the posterior myometrium measuring 0.7 cm in greatest dimension with a whorled, rubbery cut surface. The myometrium is otherwise unremarkable and is 2.0 cm thick. Representative sections of the specimen have been submitted as follows:

L: posterior endo cervix.
M: posterior endomyometrium.
N: nodule in posterior myometrium.
O: anterior endocervix.
P: anterior endomyometrium with serosal plaque.

Received fresh, labeled with the patient's name, unit number, and "appendix" is a 8.0 cm long appendix with a varying width of 0.5 cm to 0.8 cm, with attached mesoappendix 2.0 x 6.0 x 0.6 cm. The serosal surface is grossly unremarkable and the appendix is sectioned to reveal fecal contents. A representative section is submitted in cassette Q.

Received fresh, labeled with the patient's name, unit number, and "umbilical nodule" is a 3.5 x 2.0 x 0.6 cm fibrofatty tissue which is sectioned to reveal fibrous band. No masses or nodules are identified and a representative section of the firm areas is submitted in cassette R.

Received fresh, labeled with the patient's name and unit number, and "omentum" is a 32.0 x 17.0 x 4.5 cm section of omentum. There are multiple firm nodules and masses ranging in size from 0.5 to 12.0 cm. The nodules are sectioned to reveal firm white fibrous streaks and fatty tissue. Representative sections are submitted

[page 3 of 3]
into cassette S and T.

*** INTRA-OPERATIVE DIAGNOSIS ***
FROZEN SECTION DIAGNOSIS #1; OVARY, LEFT, EXCISION:
SEROUS CARCINOMA.

TCGA-30-1859

PART A: OVARY/TUBE (LEFT),
PART B: ADNEXA (RIGHT), EXCISION
PART C: UTERUS AND CERVIX, EXCISION
PART D: OMENTUM, EXCISION
PART E: APPENDIX, APPENDECTOMY
PART F: SOFT TISSUE (UMBILICAL NODULE), EXCISION

Source: NCI Genomic Data Commons file 583b765c-c2ae-4787-a84e-619db2803ef1 (TCGA-30-1859.6C4D66BC-361F-465F-B18A-7BB1A0FC7752.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).